Somatic mutation profile of tumor specimen 0DI7V0 from CCDI case PBBVKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.1 years (1,487 days).
Specimen 0DI7V0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b712eac9-63e4-4657-b7ed-0a5bb07a658b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09a0d653-8ca7-49d4-9e35-67da33e3d3ad

The open-access MAF lists 14,334 somatic variants for this specimen: 9,011 protein-altering or splice-affecting, 2,847 silent, 2,476 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,109, Silent 2,847, Intron 1,415, 3'UTR 539, Nonsense Mutation 449, 5'UTR 345, Splice Region 186, Splice Site 165, Frame Shift Ins 84, 5'Flank 78, RNA 67, 3'Flank 31.

Variants (750 of 14,334; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 267/676 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758440592, CM055898, CM065946, COSV52932932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 126/844 reads (15%) | catalogued as rs767707248; ClinVar: pathogenic; called by muse, varscan2
- AC244197.3 | c.489C>T p.G163= | Silent (SNP) | VAF 378/866 reads (44%) | catalogued as rs113993948, CD116303, CS963080, COSV61711594; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGBL2 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 399/1022 reads (39%) | catalogued as rs764666741, CM1512381; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHI1 | c.96dup p.L33Tfs*9 | Frame Shift Ins (INS) | VAF 486/1124 reads (43%) | catalogued as rs747322175; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- ALDH18A1 | c.88+1G>A p.X30_splice | Splice Site (SNP) | VAF 106/747 reads (14%) | catalogued as rs556267618; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARAF | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 385/819 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV51691221, COSV51692725, COSV51695605; called by muse, mutect2, varscan2
- ARID1B | c.5929C>T p.R1977* | Nonsense Mutation (SNP) | VAF 134/771 reads (17%) | catalogued as rs797045283, CM1310772, COSV51666367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C12orf4 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 322/793 reads (41%) | catalogued as rs749969789; ClinVar: likely pathogenic; called by muse, varscan2
- CYBB | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 332/913 reads (36%) | catalogued as rs886039337, CM960447, COSV66085637; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHCR7 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 291/725 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909764, CM980548; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.10108C>T p.R3370* | Nonsense Mutation (SNP) | VAF 369/927 reads (40%) | catalogued as rs104894787, CM084898, CS921169, COSV58909013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMPK | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 102/837 reads (12%) | catalogued as rs762280354; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.3133C>T p.R1045* | Nonsense Mutation (SNP) | VAF 384/793 reads (48%) | catalogued as rs377691013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSG1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 152/796 reads (19%) | catalogued as rs1463828394, CM1514965, COSV57138314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2570A>G p.N857S | Missense Mutation (SNP) | VAF 70/1036 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs28933370, COSV54087177; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- FAM83H | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 297/687 reads (43%) | catalogued as rs137854435, CM080344; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXO7 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 78/912 reads (9%) | catalogued as rs121918304, CM090208, COSV56679513; ClinVar: pathogenic; called by muse, mutect2
- ITPR1 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 372/881 reads (42%) | catalogued as rs886058579, COSV56974596; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- IVD | c.1240C>T p.R414W (on ENST00000651168; = p.R411W on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 314/745 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237032588, CM149150, COSV51100066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LDLR | c.1467C>A p.Y489* | Nonsense Mutation (SNP) | VAF 228/557 reads (41%) | catalogued as rs370777955, CM941044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMX1B | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 255/593 reads (43%) | catalogued as rs121909492, CM042388, CM981221, COSV62738098; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MANBA | c.960+1G>A p.X320_splice | Splice Site (SNP) | VAF 276/703 reads (39%) | catalogued as rs890870104, CS032076; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MPZ | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 337/866 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913590, CM960980, CM960981, COSV60668117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MRPS16 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 166/1435 reads (12%) | catalogued as rs104894168, CM043302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- N4BP2L2 | c.2738dup p.N913Kfs*2 (on ENST00000674422; = p.N484Kfs*2 on NM_033111.4) | Frame Shift Ins (INS) | VAF 428/1000 reads (43%) | catalogued as rs1158061584; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 124/675 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 47/1115 reads (4%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2
- PNKP | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 427/1025 reads (42%) | catalogued as rs796052850, COSV55587999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POGZ | c.3259C>T p.R1087* | Nonsense Mutation (SNP) | VAF 379/955 reads (40%) | catalogued as rs879255404, COSV51853356; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PREPL | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 371/951 reads (39%) | catalogued as rs145356495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 132/1001 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117756, COSV61005626, COSV61006865; called by muse, mutect2, varscan2
- PYCR2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 347/852 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs149587849, COSV100661511; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAB11B | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 75/660 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555690804; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 54/1386 reads (4%) | catalogued as rs1210180190, CM083063, COSV57196619; ClinVar: pathogenic; called by muse, mutect2
- RYR2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 325/872 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs727503396, COSV63664819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SLC12A3 | c.2721-1G>A p.X907_splice (on ENST00000563236 / NM_001126108.2; = p.X916_splice on NM_000339.3) | Splice Site (SNP) | VAF 410/940 reads (44%) | catalogued as rs761242621; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 96/1280 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60786475, COSV60810612; called by muse, mutect2
- TGFBR1 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 371/902 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111426349, CM064321, CM139801, COSV66625981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 418/1202 reads (35%) | catalogued as rs200944917; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 230/519 reads (44%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 476/1101 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TRIP4 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 82/934 reads (9%) | catalogued as rs869312827, CM162647, COSV56030281; ClinVar: pathogenic; called by muse, mutect2
- TRPV4 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 91/811 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs267607145, CM100594, COSV55681642; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 317/792 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as rs1318830341; called by muse, mutect2
- A4GALT | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs750440854, COSV99966581; called by muse, mutect2, varscan2
- AACS | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 58/466 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.147); catalogued as COSV55534509; called by muse, mutect2, varscan2
- AAMP | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 100/766 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1332149734; called by muse, mutect2, varscan2
- AARS2 | c.2953C>T p.L985F | Missense Mutation (SNP) | VAF 335/827 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1245608232; called by muse, mutect2, varscan2
- AASDHPPT | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 363/887 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs769999593, COSV53788350; called by muse, varscan2
- AASDHPPT | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 366/874 reads (42%) | catalogued as rs776262908, COSV53788251; called by muse, varscan2
- AATK | c.2632G>A p.G878S (on ENST00000326724 / NM_001080395.3; = p.G775S on NM_004920.2) | Missense Mutation (SNP) | VAF 80/587 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as rs751468990; called by muse, mutect2, varscan2
- ABCA1 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 537/1253 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV101036320; called by muse, mutect2, varscan2
- ABCA13 | c.9254G>A p.R3085H | Missense Mutation (SNP) | VAF 131/1050 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs760165346, COSV71291268; called by muse, mutect2, varscan2
- ABCA3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 58/760 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs769805747, COSV57056059; ClinVar: uncertain significance; called by muse, mutect2
- ABCA6 | c.3305C>A p.T1102N | Missense Mutation (SNP) | VAF 74/630 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV52635271; called by muse, mutect2, varscan2
- ABCB1 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 400/973 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963565, COSV99712139; called by muse, varscan2
- ABCB10 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 412/997 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs138468815; called by muse, mutect2, varscan2
- ABCB11 | c.3860C>A p.A1287D | Missense Mutation (SNP) | VAF 352/749 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV55590168; called by muse, mutect2, varscan2
- ABCB11 | c.3458G>A p.R1153H | Missense Mutation (SNP) | VAF 502/1134 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748862206, CM081495, CM117166, COSV55600105; called by muse, varscan2
- ABCB4 | c.2422A>G p.N808D | Missense Mutation (SNP) | VAF 46/1052 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55936876; called by muse, mutect2
- ABCB9 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 191/465 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as rs1325577131; called by muse, mutect2, varscan2
- ABCC1 | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 240/626 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936320134; called by muse, mutect2, varscan2
- ABCC1 | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 310/686 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs377013600; called by muse, mutect2, varscan2
- ABCC3 | c.4210C>A p.L1404M | Missense Mutation (SNP) | VAF 105/618 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1317237681; called by muse, mutect2, varscan2
- ABCC4 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 135/1006 reads (13%) | catalogued as rs1036187257; called by muse, mutect2, varscan2
- ABCC6 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 268/661 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749568041; called by muse, mutect2, varscan2
- ABCC8 | c.3867+7G>A | Splice Region (SNP) | VAF 195/458 reads (43%) | catalogued as rs372198547, CS131808; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1557052345; called by muse, varscan2
- ABCD1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 210/541 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as rs1557055333, CD961757; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCF1 | c.866C>T p.A289V (on ENST00000326195 / NM_001025091.2; = p.A251V on NM_001090.3) | Missense Mutation (SNP) | VAF 40/1052 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.121); catalogued as rs768108149, COSV100400735; called by muse, mutect2
- ABCF1 | c.1724C>T p.T575M (on ENST00000326195 / NM_001025091.2; = p.T537M on NM_001090.3) | Missense Mutation (SNP) | VAF 306/731 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as rs370684998; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 246/618 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1559776076; called by muse, mutect2, varscan2
- ABHD16A | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 198/438 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs563272053; called by muse, varscan2
- ABHD16A | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 19/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013364; called by muse, mutect2
- ABHD17A | c.532G>A p.G178S (on ENST00000292577 / NM_001130111.2; = p.G229S on NM_031213.4) | Missense Mutation (SNP) | VAF 139/978 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as rs755208797; called by muse, varscan2
- ABHD18 | c.914G>A p.R305H (on ENST00000398965 / NM_001039717.2; = p.R212H on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 332/849 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as rs767049484; called by muse, mutect2, varscan2
- ABI2 | c.1118G>A p.R373H (on ENST00000295851 / NM_001375719.1; = p.R306H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 405/940 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1457719361, COSV53689816; called by muse, mutect2, varscan2
- ABLIM1 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 253/702 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1436893329; called by muse, mutect2, varscan2
- ABTB2 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as rs1449069487, COSV54397364; called by muse, mutect2
- AC004922.1 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 105/669 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs776539765, COSV53163583; called by muse, mutect2, varscan2
- AC006059.2 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 251/590 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs141942240; called by muse, mutect2, varscan2
- AC013489.1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 341/820 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs762523583, COSV51550593; called by muse, mutect2, varscan2
- AC093525.2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 285/616 reads (46%) | PolyPhen benign (0.003); catalogued as COSV53549638, COSV53550148; called by muse, mutect2, varscan2
- AC242842.3 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 37/411 reads (9%) | catalogued as rs1233186591; called by muse, mutect2, varscan2
- ACAD11 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 178/1055 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs377349315; called by muse, mutect2, varscan2
- ACAN | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 230/560 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs772320528; called by muse, varscan2
- ACOT12 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 353/930 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs564306951, COSV56892647, COSV56894194; called by muse, mutect2, varscan2
- ACOT7 | c.376G>A p.A126T (on ENST00000377855 / NM_181864.3; = p.A116T on NM_007274.4) | Missense Mutation (SNP) | VAF 272/716 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766402526, COSV64115764; called by muse, varscan2
- ACOT7 | c.325C>T p.R109C (on ENST00000377855 / NM_181864.3; = p.R99C on NM_007274.4) | Missense Mutation (SNP) | VAF 322/719 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs201654646, COSV64112946; called by muse, varscan2
- ACOXL | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 203/544 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265915879; called by muse, mutect2, varscan2
- ACP1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 274/657 reads (42%) | catalogued as rs1310093778, COSV99681633; called by muse, varscan2
- ACP6 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 225/436 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1004088042; called by muse, mutect2, varscan2
- ACSL4 | c.1955A>C p.E652A (on ENST00000340800 / NM_022977.2; = p.E611A on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/789 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs953387465; called by muse, mutect2, varscan2
- ACSL6 | c.691G>A p.E231K (on ENST00000379240; = p.E256K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 326/736 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV57297051; called by muse, mutect2, varscan2
- ACSS3 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 400/913 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1054511021; called by muse, mutect2, varscan2
- ACTG2 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 97/703 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs199739994; called by muse, mutect2, varscan2
- ACTL7B | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 120/727 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1480148606, COSV65927351; called by muse, mutect2, varscan2
- ACTN4 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 303/687 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1433117986; called by muse, mutect2, varscan2
- ACTR2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 380/859 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53202628; called by muse, varscan2
- ACVRL1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 359/863 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66359887; called by muse, mutect2, varscan2
- ADA | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 331/802 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs776103734, COSV65741032; called by muse, mutect2, varscan2
- ADA2 | c.1474A>G p.T492A (on ENST00000262607; = p.T251A on NM_177405.3) | Missense Mutation (SNP) | VAF 422/1019 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780459163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADA2 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 439/1067 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52834458; called by muse, mutect2, varscan2
- ADAM10 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 302/770 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs770353099; called by muse, mutect2, varscan2
- ADAM17 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 105/1015 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as rs538865826; called by muse, varscan2
- ADAM18 | c.1097G>T p.R366I | Missense Mutation (SNP) | VAF 107/715 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV55847024, COSV55853980; called by muse, mutect2, varscan2
- ADAM23 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 356/863 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1043720622; called by muse, mutect2, varscan2
- ADAM30 | c.746A>C p.H249P | Missense Mutation (SNP) | VAF 474/1103 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as rs775296308; called by muse, mutect2, varscan2
- ADAM33 | c.600+8G>A | Splice Region (SNP) | VAF 50/525 reads (10%) | catalogued as rs1351425254; called by muse, mutect2
- ADAM7 | c.963T>C p.D321= | Splice Region (SNP) | VAF 54/962 reads (6%) | catalogued as COSV51543168; called by muse, mutect2
- ADAMTS10 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 115/512 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs1555736845; called by muse, mutect2, varscan2
- ADAMTS10 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 358/875 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV54359485; called by muse, varscan2
- ADAMTS16 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 491/1197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755888082; called by muse, mutect2, varscan2
- ADAMTS16 | c.2647G>A p.V883M | Missense Mutation (SNP) | VAF 276/631 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs777995259, COSV56999761, COSV57004323; called by muse, mutect2, varscan2
- ADAMTS20 | c.3539G>A p.R1180H | Missense Mutation (SNP) | VAF 371/896 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140458220; called by muse, mutect2, varscan2
- ADAMTS3 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 352/839 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371868606, COSV99710273; called by muse, mutect2, varscan2
- ADAMTS3 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 64/790 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142268705; called by muse, mutect2
- ADAMTS4 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 78/1066 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs759418589, COSV63489277; called by muse, mutect2
- ADAMTS6 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 152/1133 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV66861791; called by muse, mutect2, varscan2
- ADAMTS9 | c.911G>T p.R304I | Missense Mutation (SNP) | VAF 161/937 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV55784710, COSV99900020; called by muse, mutect2, varscan2
- ADAMTSL1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 131/1192 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750236831, COSV52826019; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 116/834 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.017); catalogued as rs553601312; called by muse, varscan2
- ADAMTSL1 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 40/794 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as COSV101002033, COSV65892039; called by muse, mutect2
- ADAT1 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 491/1196 reads (41%) | catalogued as rs750292116; called by muse, mutect2, varscan2
- ADCK1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 129/721 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs779163496, COSV53078794; called by muse, mutect2, varscan2
- ADCK5 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 77/600 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554860747; called by muse, varscan2
- ADCY1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1022292664; called by muse, mutect2, varscan2
- ADCY1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 360/771 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs748614348, COSV52030450; called by muse, mutect2, varscan2
- ADCY4 | c.2167C>T p.H723Y | Missense Mutation (SNP) | VAF 91/613 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60256179; called by muse, mutect2, varscan2
- ADCY5 | c.3550G>A p.V1184M | Missense Mutation (SNP) | VAF 138/332 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758210719; called by muse, mutect2, varscan2
- ADCY5 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 220/511 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs1045756030; called by muse, mutect2, varscan2
- ADCY6 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 60/474 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs1188100134, COSV57169419; called by muse, mutect2, varscan2
- ADCY7 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs935776376; called by muse, mutect2, varscan2
- ADD3 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 164/801 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as rs898391855, COSV99523320; called by muse, mutect2, varscan2
- ADGB | c.4022G>A p.R1341H | Missense Mutation (SNP) | VAF 335/813 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs762627387, COSV58846726; called by muse, mutect2, varscan2
- ADGRA1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 245/531 reads (46%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as rs773237929; called by muse, mutect2, varscan2
- ADGRA1 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 64/769 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV66926430; called by muse, mutect2
- ADGRA1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs780856356; called by muse, varscan2
- ADGRA1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 190/449 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.21); catalogued as rs754755741; called by muse, varscan2
- ADGRB1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 255/555 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60102121; called by muse, mutect2, varscan2
- ADGRB1 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 291/664 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs748528325; called by muse, mutect2, varscan2
- ADGRB2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 96/593 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs199894607, COSV57074478; called by muse, varscan2
- ADGRE5 | c.1595G>T p.S532I (on ENST00000242786 / NM_078481.4; = p.S439I on NM_001784.5) | Missense Mutation (SNP) | VAF 122/659 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54392827; called by muse, mutect2, varscan2
- ADGRF1 | c.2336G>A p.S779N | Missense Mutation (SNP) | VAF 332/689 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51947806; called by muse, mutect2, varscan2
- ADGRF4 | c.2072T>G p.M691R | Missense Mutation (SNP) | VAF 89/735 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV51954376; called by muse, mutect2, varscan2
- ADGRF5 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 300/698 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs548238446; called by mutect2, varscan2
- ADGRG7 | c.229+1G>A p.X77_splice | Splice Site (SNP) | VAF 363/882 reads (41%) | catalogued as rs748745962; called by muse, mutect2, varscan2
- ADGRV1 | c.4100C>T p.T1367M | Missense Mutation (SNP) | VAF 295/753 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1271079102, COSV67982080; called by muse, mutect2, varscan2
- ADI1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 92/675 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772279164, COSV59376584; called by muse, varscan2
- ADIPOR1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 358/871 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.61); catalogued as COSV100579629; called by muse, mutect2, varscan2
- ADPRHL1 | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.81); catalogued as rs1207178056; called by muse, mutect2
- ADPRHL1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 53/511 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs570992371, COSV62909809; called by muse, mutect2, varscan2
- ADRA2B | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 181/458 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs570135294; called by muse, mutect2, varscan2
- ADRB2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 261/766 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs377115303, COSV60005825; called by muse, mutect2, varscan2
- AEBP1 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 257/675 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775745840; called by muse, mutect2, varscan2
- AFDN | c.4937C>A p.A1646D (on ENST00000447894 / NM_001366320.1; = p.A1644D on NM_001040000.3) | Missense Mutation (SNP) | VAF 131/873 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60050734; called by muse, mutect2, varscan2
- AFF3 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 403/715 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57853115; called by muse, mutect2, varscan2
- AFMID | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 327/806 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs200095741; called by muse, mutect2, varscan2
- AGA | c.939C>T p.Y313= | Splice Region (SNP) | VAF 140/790 reads (18%) | catalogued as rs752718514; called by muse, mutect2, varscan2
- AGAP3 | c.251C>T p.T84M (on ENST00000622464; = p.T120M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/570 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766557940; called by muse, varscan2
- AGAP3 | c.598+7C>T | Splice Region (SNP) | VAF 252/568 reads (44%) | catalogued as rs1356477643; called by muse, mutect2, varscan2
- AGAP3 | c.866C>T p.T289M (on ENST00000622464; = p.T325M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/536 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs191096334, COSV58994099; called by muse, mutect2, varscan2
- AGAP3 | c.1175C>T p.T392M (on ENST00000622464; = p.T428M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 354/862 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745840242, COSV68244149; called by muse, mutect2, varscan2
- AGAP4 | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 79/236 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs143658188; called by muse, mutect2, varscan2
- AGAP6 | c.515C>T p.A172V (on ENST00000374056 / NM_001365867.1; = p.A195V on NM_001077665.2) | Missense Mutation (SNP) | VAF 63/1262 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs782679180, COSV65017585; called by muse, mutect2
- AGAP6 | c.590C>T p.S197L (on ENST00000374056 / NM_001365867.1; = p.S220L on NM_001077665.2) | Missense Mutation (SNP) | VAF 124/962 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1554864498, COSV65017963; called by muse, mutect2, varscan2
- AGBL5 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 339/796 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs545834161, COSV64080011; called by muse, mutect2, varscan2
- AGFG2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 70/754 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs780962444, COSV53544298; called by muse, mutect2
- AGL | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 409/940 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as rs748680148; called by muse, mutect2, varscan2
- AGRN | c.4988C>T p.A1663V | Missense Mutation (SNP) | VAF 207/535 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs753922672, COSV65071446; called by muse, varscan2
- AHCTF1 | c.5896C>T p.R1966C (on ENST00000366508; = p.R1940C on NM_015446.5) | Missense Mutation (SNP) | VAF 294/708 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1226434538, COSV58251075; called by muse, varscan2
- AHCTF1 | c.1663C>T p.R555* (on ENST00000366508; = p.R529* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 481/1261 reads (38%) | catalogued as COSV58248152; called by muse, mutect2, varscan2
- AHCTF1 | c.1190C>T p.S397F (on ENST00000366508; = p.S371F on NM_015446.5) | Missense Mutation (SNP) | VAF 56/1028 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.222); catalogued as rs1558263192; called by muse, mutect2
- AHCTF1 | c.109C>T p.R37* (on ENST00000366508; = p.R11* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 45/818 reads (6%) | catalogued as rs866640499, COSV100403238; called by muse, mutect2
- AHCYL2 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 449/1072 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61485399; called by muse, mutect2, varscan2
- AHDC1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 65/562 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs369860059; called by muse, mutect2, varscan2
- AHI1 | c.308A>C p.N103T | Missense Mutation (SNP) | VAF 40/1260 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1381810348; called by muse, mutect2
- AHNAK | c.10714C>A p.L3572M | Missense Mutation (SNP) | VAF 84/556 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs368054244; called by muse, mutect2, varscan2
- AHRR | c.2051C>T p.T684M | Missense Mutation (SNP) | VAF 295/675 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.533); catalogued as rs748125683, COSV57095118; called by muse, mutect2, varscan2
- AIPL1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 291/766 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759934433; called by muse, mutect2, varscan2
- AJM1 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56035055; called by muse, mutect2
- AJUBA | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 16/242 reads (7%) | catalogued as COSV99401200; called by muse, mutect2
- AK5 | c.1423C>T p.R475C (on ENST00000354567 / NM_174858.3; = p.R449C on NM_012093.4) | Missense Mutation (SNP) | VAF 341/781 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs554863447, COSV60981985; called by muse, mutect2, varscan2
- AKAP11 | c.4948C>T p.L1650F | Missense Mutation (SNP) | VAF 185/1164 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs776327237, COSV50300438; called by muse, mutect2, varscan2
- AKAP3 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 303/787 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs749738318, COSV57414538; called by muse, mutect2, varscan2
- AKT1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 376/846 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62573189; called by muse, mutect2, varscan2
- AL136295.1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 264/488 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs138817054; called by muse, varscan2
- AL645922.1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 341/935 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559980890; called by muse, mutect2, varscan2
- ALDH18A1 | c.2109C>T p.D703= | Splice Region (SNP) | VAF 291/706 reads (41%) | catalogued as rs779516879, COSV64663632; called by muse, mutect2, varscan2
- ALDH8A1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 258/601 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1452823837; called by muse, mutect2, varscan2
- ALG1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 329/1342 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs758197753, COSV52158405; called by muse, varscan2
- ALG10 | c.1336G>T p.V446F | Missense Mutation (SNP) | VAF 449/1075 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV56791508; called by muse, mutect2, varscan2
- ALG11 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 398/1070 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204420316, COSV73000650; called by muse, mutect2, varscan2
- ALG12 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 283/752 reads (38%) | catalogued as rs547640376; called by muse, mutect2
- ALG13 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 225/586 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs959903137; called by muse, mutect2, varscan2
- ALKBH2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 100/654 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs929361040; called by muse, mutect2, varscan2
- ALOX12B | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 185/445 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1338807370; called by muse, mutect2, varscan2
- ALOX5 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 510/1236 reads (41%) | catalogued as COSV65551085, COSV65552066; called by muse, mutect2, varscan2
- ALOX5 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 422/1068 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as rs201769753, COSV100979973; called by muse, mutect2, varscan2
- ALOX5AP | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 322/856 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs760124781; called by muse, varscan2
- ALPL | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 285/732 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.255); catalogued as rs1287863636; called by muse, mutect2, varscan2
- ALS2 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 446/995 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs761444982, COSV51889739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2CL | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 77/556 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs763639281; called by muse, mutect2, varscan2
- AMBRA1 | c.3670C>T p.R1224* (on ENST00000458649 / NM_001367468.1; = p.R1134* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 203/518 reads (39%) | catalogued as rs1023861260, COSV54053486; called by muse, mutect2, varscan2
- AMER1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.163); catalogued as COSV57656071; called by muse, varscan2
- AMER1 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 167/438 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1328313050; called by muse, mutect2, varscan2
- AMMECR1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 155/439 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1247385721; called by muse, mutect2, varscan2
- AMOT | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 317/780 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs761571019; called by muse, mutect2, varscan2
- AMOTL1 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 243/539 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.19); catalogued as rs1298257822; called by muse, mutect2, varscan2
- AMPD2 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 276/637 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456066824, COSV56649874; called by muse, mutect2, varscan2
- ANAPC2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 230/563 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV60571641; called by muse, mutect2, varscan2
- ANGEL1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 85/797 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs375071846; called by muse, mutect2, varscan2
- ANGPT4 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 237/514 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs775920001, COSV67921142; called by muse, mutect2, varscan2
- ANGPTL2 | c.1139A>C p.E380A | Missense Mutation (SNP) | VAF 85/480 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as rs1260173312; called by muse, mutect2, varscan2
- ANHX | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 321/733 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as rs1425360577; called by muse, mutect2, varscan2
- ANK2 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 555/1226 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV52151630; called by muse, mutect2, varscan2
- ANK3 | c.12646C>T p.R4216* (on ENST00000280772 / NM_001320874.2; = p.R840* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 79/1299 reads (6%) | catalogued as COSV55050880; called by muse, mutect2
- ANK3 | c.5306C>T p.T1769I | Missense Mutation (SNP) | VAF 385/846 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs745734310, COSV55048547, COSV55074000; called by muse, mutect2, varscan2
- ANK3 | c.3355A>G p.K1119E (on ENST00000280772 / NM_001320874.2; = p.K253E on NM_001149.3) | Missense Mutation (SNP) | VAF 92/690 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV55072030; called by muse, mutect2, varscan2
- ANKEF1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 151/1130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1281370773, COSV65692065; called by muse, mutect2, varscan2
- ANKIB1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 598/684 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs187952686; called by muse, mutect2, varscan2
- ANKK1 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 66/624 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs775487122; called by muse, mutect2, varscan2
- ANKLE1 | c.653C>T p.T218M (on ENST00000394458; = p.T164M on NM_152363.6) | Missense Mutation (SNP) | VAF 279/662 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs754207976; called by muse, mutect2, varscan2
- ANKRD12 | c.2444T>C p.I815T | Missense Mutation (SNP) | VAF 52/1081 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1408601159; called by muse, mutect2
- ANKRD12 | c.4264C>T p.P1422S | Missense Mutation (SNP) | VAF 276/668 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs544466688; called by muse, mutect2, varscan2
- ANKRD13C | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 60/1128 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV99256442; called by muse, mutect2
- ANKRD18A | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 470/1099 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs575493959, COSV68802647; called by muse, mutect2, varscan2
- ANKRD27 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 139/856 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs372414887; called by muse, mutect2, varscan2
- ANKRD33 | c.230G>A p.R77H (on ENST00000340970 / NM_001304459.2; = p.R212H on NM_182608.4) | Missense Mutation (SNP) | VAF 285/736 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs751233923, COSV56604835; called by muse, mutect2, varscan2
- ANKRD35 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 27/557 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV62909927, COSV62911073; called by muse, mutect2
- ANKRD39 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 341/844 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs147578390; called by muse, mutect2, varscan2
- ANKRD52 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 163/839 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1368235699, COSV57285494; called by muse, mutect2, varscan2
- ANKS1B | c.2243A>C p.N748T | Missense Mutation (SNP) | VAF 171/1231 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541366843; called by muse, mutect2, varscan2
- ANKS3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs929947683; called by muse, mutect2, varscan2
- ANKS6 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 163/892 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs200818398; called by muse, mutect2, varscan2
- ANKUB1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 398/937 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774131451, COSV67167718; called by muse, mutect2, varscan2
- ANOS1 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 52/1136 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV52917251; called by muse, mutect2
- ANTXR1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 346/791 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58011180; called by muse, mutect2, varscan2
- AOPEP | c.2365G>A p.A789T (on ENST00000375315 / NM_001193329.1; = p.A690T on NM_032823.5) | Missense Mutation (SNP) | VAF 288/724 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs1484962691; called by muse, mutect2, varscan2
- AP1B1 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 368/1036 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.776); catalogued as rs767707068; called by muse, mutect2
- AP1B1 | c.684C>A p.N228K | Missense Mutation (SNP) | VAF 319/754 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.223); catalogued as COSV100434826; called by mutect2, varscan2
- AP2A1 | c.280-1G>T p.X94_splice | Splice Site (SNP) | VAF 30/554 reads (5%) | catalogued as COSV62819232; called by muse, mutect2
- AP2A1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 237/635 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62817197, COSV62820811; called by muse, mutect2, varscan2
- AP3B1 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 267/655 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs774857414, COSV54880967; called by muse, mutect2, varscan2
- AP3D1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 308/684 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1452569078; called by muse, mutect2, varscan2
- AP5B1 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs745506104, COSV100375979; called by muse, mutect2
- AP5B1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 156/399 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs778961738, COSV100376046; called by muse, mutect2, varscan2
- APBA1 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 171/977 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs749295663, COSV55222227; called by muse, mutect2, varscan2
- APBA1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 281/645 reads (44%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1279410417, COSV55233793; called by muse, mutect2, varscan2
- APC | c.7877C>A p.T2626N | Missense Mutation (SNP) | VAF 442/1002 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs730881268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 152/318 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs938566336; called by muse, varscan2
- APC2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 234/586 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as rs749078066, COSV99279970; called by muse, varscan2
- APC2 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 128/304 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as rs753549087, COSV52018367; called by muse, mutect2, varscan2
- APC2 | c.3716G>A p.R1239H | Missense Mutation (SNP) | VAF 130/363 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs776326309; called by muse, varscan2
- APC2 | c.6551G>A p.R2184H | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763459814; called by muse, mutect2, varscan2
- APEH | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 42/804 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1410919552; called by muse, mutect2
- APLP1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 240/587 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs892180063; called by muse, mutect2, varscan2
- APOA2 | c.-22C>T | Splice Region (SNP) | VAF 83/481 reads (17%) | catalogued as rs779237488; called by muse, mutect2, varscan2
- APOB | c.3705C>A p.S1235R | Missense Mutation (SNP) | VAF 245/651 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs774105545; called by muse, mutect2, varscan2
- APOB | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 163/999 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs750454285; called by muse, mutect2, varscan2
- APOBEC3C | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 379/890 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs376538641; called by muse, mutect2, varscan2
- APOBEC3G | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 422/1101 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as rs754373002, COSV101349080; called by muse, mutect2, varscan2
- APOBEC4 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 187/1109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs775440926, COSV58018276; called by muse, mutect2, varscan2
- APOL3 | c.815A>G p.D272G (on ENST00000349314 / NM_145640.2; = p.D201G on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/724 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as rs1377111622; called by muse, varscan2
- APOL4 | c.196G>A p.V66M (on ENST00000352371 / NM_145660.2; = p.V63M on NM_030643.4) | Missense Mutation (SNP) | VAF 284/783 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs763230967; called by muse, mutect2, varscan2
- AQP11 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 199/472 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1238495199, COSV57993192; called by muse, mutect2, varscan2
- AQP12B | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 321/535 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs373693752, COSV68184107; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 238/556 reads (43%) | catalogued as rs3215969; called by mutect2, varscan2
- AQR | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 229/575 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV50033675; called by muse, mutect2, varscan2
- ARAP1 | c.1948C>T p.R650C (on ENST00000393609 / NM_001040118.2; = p.R405C on NM_015242.4) | Missense Mutation (SNP) | VAF 314/675 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs770843799; called by muse, mutect2, varscan2
- ARAP1 | c.1468G>A p.V490M (on ENST00000393609 / NM_001040118.2; = p.V245M on NM_015242.4) | Missense Mutation (SNP) | VAF 402/929 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs762932490; called by muse, varscan2
- AREL1 | c.2194G>A p.V732I | Missense Mutation (SNP) | VAF 183/433 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as rs777263416; called by muse, mutect2, varscan2
- AREL1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs746270046, COSV62666333; called by muse, varscan2
- ARFGEF2 | c.4345A>G p.N1449D | Missense Mutation (SNP) | VAF 376/916 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1194425052; called by muse, mutect2, varscan2
- ARFGEF3 | c.3592C>T p.R1198W | Missense Mutation (SNP) | VAF 118/934 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1482571015, COSV52461268; called by muse, mutect2, varscan2
- ARHGAP10 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 435/1022 reads (43%) | catalogued as COSV100331740; called by muse, mutect2, varscan2
- ARHGAP20 | c.1866C>A p.D622E | Missense Mutation (SNP) | VAF 298/757 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1242064852; called by muse, mutect2, varscan2
- ARHGAP21 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 418/979 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs764390405; called by muse, mutect2, varscan2
- ARHGAP22 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 482/1088 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749030451; called by muse, mutect2, varscan2
- ARHGAP22 | c.1953G>A p.M651I | Missense Mutation (SNP) | VAF 114/967 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV50997435; called by muse, varscan2
- ARHGAP27 | c.2135G>A p.R712H (on ENST00000428638 / NM_001282290.1; = p.R371H on NM_199282.3) | Missense Mutation (SNP) | VAF 282/652 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs1301296091, COSV104424363, COSV65359018; called by muse, mutect2, varscan2
- ARHGAP29 | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 387/1154 reads (34%) | catalogued as COSV53110173; called by muse, mutect2, varscan2
- ARHGAP30 | c.2768G>A p.R923H (on ENST00000368013 / NM_001025598.2; = p.R712H on NM_181720.3) | Missense Mutation (SNP) | VAF 194/407 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748205506, COSV63519608; called by muse, mutect2, varscan2
- ARHGAP31 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 469/1057 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368670775; called by muse, mutect2, varscan2
- ARHGAP33 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 254/636 reads (40%) | catalogued as rs753643359; called by muse, mutect2, varscan2
- ARHGAP35 | c.2597C>A p.S866Y | Missense Mutation (SNP) | VAF 359/843 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68329306, COSV68332376; called by muse, mutect2, varscan2
- ARHGAP5 | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 114/747 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs758675410, COSV61534139; called by muse, mutect2, varscan2
- ARHGEF1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 175/392 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs782364939, COSV100528907; called by muse, mutect2, varscan2
- ARHGEF10L | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 287/687 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553508294; called by muse, mutect2, varscan2
- ARHGEF12 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 77/1196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963893223; called by muse, mutect2
- ARHGEF12 | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 68/1084 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs770268450, COSV100755005, COSV63104928; called by muse, mutect2
- ARHGEF16 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 287/671 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776339132; called by muse, mutect2, varscan2
- ARHGEF17 | c.3788G>A p.R1263H | Missense Mutation (SNP) | VAF 244/546 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs747501115; called by muse, mutect2, varscan2
- ARHGEF2 | c.2759G>A p.R920Q (on ENST00000361247 / NM_001162383.2; = p.R892Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 385/1009 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs539956003, COSV100560537, COSV58115384; called by muse, mutect2, varscan2
- ARHGEF35 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 62/456 reads (14%) | PolyPhen possibly damaging (0.567); catalogued as rs767703832, COSV65313056; called by muse, mutect2, varscan2
- ARHGEF38 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 504/1271 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs778608312, COSV70364901; called by muse, mutect2, varscan2
- ARHGEF40 | c.2528C>A p.A843D | Missense Mutation (SNP) | VAF 66/583 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.767); catalogued as rs1394191578; called by muse, mutect2, varscan2
- ARHGEF40 | c.4231C>T p.L1411F | Missense Mutation (SNP) | VAF 213/538 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs781655883; called by muse, mutect2, varscan2
- ARHGEF6 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 329/897 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV99166344, COSV99166345; called by muse, mutect2, varscan2
- ARID1A | c.6458G>A p.R2153H | Missense Mutation (SNP) | VAF 136/715 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs747780610; called by muse, mutect2, varscan2
- ARID1B | c.4868C>T p.A1623V | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1022849043; called by muse, mutect2
- ARID2 | c.3048A>T p.Q1016H | Missense Mutation (SNP) | VAF 287/620 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV57603310; called by muse, mutect2, varscan2
- ARID3A | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs765729766; called by muse, varscan2
- ARID4A | c.3134C>T p.S1045L | Missense Mutation (SNP) | VAF 175/1097 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1340980182; called by muse, mutect2, varscan2
- ARID5B | c.1864T>C p.Y622H | Missense Mutation (SNP) | VAF 297/691 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as COSV99690312; called by muse, mutect2, varscan2
- ARIH2 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 366/796 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as COSV62703933; called by muse, mutect2, varscan2
- ARIH2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 250/596 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs769437830; called by muse, varscan2
- ARMC3 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 104/678 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53060202; called by muse, varscan2
- ARMC5 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as rs1386704670; called by muse, mutect2, varscan2
- ARMH1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 189/523 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs764885693; called by muse, mutect2, varscan2
- ARMH4 | c.1715G>T p.S572I | Missense Mutation (SNP) | VAF 65/553 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV50771478; called by muse, mutect2, varscan2
- ARRDC4 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 236/562 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as rs1334568804; called by muse, mutect2, varscan2
- ART3 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 388/963 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443051842; called by muse, mutect2, varscan2
- ART4 | c.853+1G>A p.X285_splice | Splice Site (SNP) | VAF 214/554 reads (39%) | catalogued as COSV57452271, COSV99966868; called by muse, mutect2, varscan2
- ARX | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 72/934 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs769996976; ClinVar: uncertain significance; called by muse, mutect2
- ASAH2 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 89/825 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs768710219; called by muse, mutect2, varscan2
- ASB10 | c.841C>A p.L281I (on ENST00000420175 / NM_001142459.2; = p.L266I on NM_080871.4) | Missense Mutation (SNP) | VAF 69/554 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.87); catalogued as rs1351910593, COSV99318777; called by muse, mutect2, varscan2
- ASB10 | c.460G>A p.E154K (on ENST00000420175 / NM_001142459.2; = p.E139K on NM_080871.4) | Missense Mutation (SNP) | VAF 157/386 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs139505650; called by muse, mutect2, varscan2
- ASB12 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 203/522 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1431904864; called by muse, varscan2
- ASB16 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 327/778 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs146000947, COSV53233896; called by muse, mutect2, varscan2
- ASCC2 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 135/939 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs750342179, COSV57073246; called by muse, mutect2, varscan2
- ASCC3 | c.2758A>G p.T920A | Missense Mutation (SNP) | VAF 112/798 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV61234556; called by muse, varscan2
- ASGR2 | c.89G>T p.R30M | Missense Mutation (SNP) | VAF 299/738 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV54691433; called by muse, mutect2, varscan2
- ASH1L | c.8026C>T p.R2676W (on ENST00000368346 / NM_001366177.2; = p.R2671W on NM_018489.3) | Missense Mutation (SNP) | VAF 86/1110 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1384675040; called by muse, mutect2
- ASH1L | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 114/881 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs374072309; called by muse, varscan2
- ASIC3 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 200/505 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.671); catalogued as rs1275942791; called by muse, mutect2, varscan2
- ASPH | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 434/970 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV62861528; called by muse, mutect2, varscan2
- ASTE1 | c.-24C>T | Splice Region (SNP) | VAF 235/639 reads (37%) | catalogued as rs747685990, COSV99393570; called by muse, mutect2, varscan2
- ASTN2 | c.1591G>A p.G531R (on ENST00000313400 / NM_001365069.1; = p.G480R on NM_014010.5) | Missense Mutation (SNP) | VAF 316/797 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776296190, COSV57752943, COSV57821120; called by muse, mutect2, varscan2
- ASXL2 | c.4061T>C p.V1354A | Missense Mutation (SNP) | VAF 102/693 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs778738425; called by muse, mutect2, varscan2
- ASXL3 | c.4148C>T p.A1383V | Missense Mutation (SNP) | VAF 36/700 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV52457361; called by muse, mutect2
- ATAD3A | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 359/864 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554255312; called by muse, mutect2, varscan2
- ATAD3C | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 134/382 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs202189170; called by muse, mutect2, varscan2
- ATF2 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 578/1348 reads (43%) | catalogued as COSV51376454; called by muse, mutect2, varscan2
- ATG2A | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 447/998 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1343688749; called by muse, mutect2, varscan2
- ATG2B | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 250/749 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs753413792; called by muse, mutect2, varscan2
- ATG7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 273/692 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs1005891334, COSV100608096; called by muse, mutect2, varscan2
- ATL3 | c.1626G>T p.*542Yext*58 | Nonstop Mutation (SNP) | VAF 377/868 reads (43%) | catalogued as COSV60297933; called by muse, varscan2
- ATOH1 | c.311A>C p.E104A | Missense Mutation (SNP) | VAF 38/581 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100024519; called by muse, mutect2
- ATP10A | c.4435C>T p.R1479* | Nonsense Mutation (SNP) | VAF 30/852 reads (4%) | catalogued as rs1051708992, COSV63518302; called by muse, mutect2
- ATP10A | c.4011G>T p.E1337D | Missense Mutation (SNP) | VAF 326/739 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV63520986; called by muse, mutect2, varscan2
- ATP11A | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 57/944 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1411005250, COSV52110812; called by muse, mutect2
- ATP1A3 | c.1298G>A p.R433H (on ENST00000545399 / NM_001256214.2; = p.R420H on NM_152296.5) | Missense Mutation (SNP) | VAF 108/669 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV57487503; called by muse, mutect2, varscan2
- ATP1A3 | c.94C>T p.R32C (on ENST00000545399 / NM_001256214.2; = p.R19C on NM_152296.5) | Missense Mutation (SNP) | VAF 231/532 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs782229302, COSV57487195; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP2A2 | c.545-6G>A | Splice Region (SNP) | VAF 354/839 reads (42%) | catalogued as rs766741286; called by muse, mutect2, varscan2
- ATP2C2 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 60/926 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771774140; called by muse, mutect2
- ATP2C2 | c.1241C>A p.T414N | Missense Mutation (SNP) | VAF 52/851 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.255); catalogued as COSV99297659; called by muse, mutect2
- ATP6V0A4 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 52/1249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276962394, CM162241, COSV59474065; called by muse, mutect2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 404/948 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V0D2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 89/606 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.586); catalogued as rs1343831181, COSV53413606, COSV53416972; called by muse, mutect2, varscan2
- ATP6V0E2 | c.127G>A p.A43T (on ENST00000425642; = p.A92T on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/589 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs369379550; called by muse, mutect2, varscan2
- ATP6V1B2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 275/743 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV52353491; called by muse, mutect2, varscan2
- ATP7B | c.4327G>A p.A1443T | Missense Mutation (SNP) | VAF 238/582 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs764383437; called by muse, varscan2
- ATP7B | c.4039G>A p.G1347S | Missense Mutation (SNP) | VAF 216/601 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587783318, CM141676, COSV99666422; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- ATP7B | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 241/532 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs769531525, CM061647, COSV54437118; called by muse, mutect2, varscan2
- ATP8A2 | c.1718G>T p.R573I | Missense Mutation (SNP) | VAF 98/888 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54966222; called by muse, mutect2, varscan2
- ATP8B2 | c.3331A>G p.I1111V (on ENST00000672630; = p.I1078V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/1186 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1235716218; called by muse, mutect2
- ATP9A | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 296/736 reads (40%) | catalogued as rs1161132652, COSV100124742; called by muse, mutect2, varscan2
- ATRN | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 436/1034 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs761966458, COSV53531827; called by muse, mutect2, varscan2
- ATRX | c.3256G>T p.A1086S | Missense Mutation (SNP) | VAF 350/882 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); catalogued as COSV64882760; called by muse, mutect2, varscan2
- ATRX | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 391/872 reads (45%) | catalogued as COSV64885777; called by muse, varscan2
- ATXN1L | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405847666, COSV70235623; called by muse, mutect2, varscan2
- ATXN2L | c.2867G>A p.G956D | Missense Mutation (SNP) | VAF 87/746 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs866137830; called by muse, mutect2, varscan2
- ATXN3L | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 371/891 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1197155274; called by muse, mutect2, varscan2
- ATXN7L3 | c.674G>A p.R225H (on ENST00000389384 / NM_001382309.1; = p.R232H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/822 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV60228759; called by muse, mutect2
- AUTS2 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 407/1069 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs761324549; called by muse, mutect2, varscan2
- AUTS2 | c.3178C>T p.R1060C | Missense Mutation (SNP) | VAF 83/863 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61390104; called by muse, mutect2
- AVL9 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 349/826 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs117025770; called by muse, mutect2, varscan2
- AVPR1A | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV54546265; called by muse, mutect2, varscan2
- AVPR1B | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 218/520 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs368239814; called by muse, mutect2
- AVPR1B | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 272/709 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as rs782514717; called by muse, mutect2
- AXIN2 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 74/1176 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.62); catalogued as rs368502813; called by muse, mutect2
- AXIN2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 126/1305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61055422; called by muse, mutect2
- B3GAT1 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 204/464 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56996355, COSV57000249; called by muse, mutect2, varscan2
- B3GAT1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 307/755 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs780367245, COSV56996477; called by muse, mutect2, varscan2
- B3GNT2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 422/1063 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs370583197; called by muse, mutect2, varscan2
- B3GNT6 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs782568909; called by muse, mutect2
- B3GNT8 | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 94/592 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV54198053; called by muse, varscan2
- B4GALT3 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 164/357 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs751634436; called by muse, mutect2, varscan2
- BACH2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs747189218; called by muse, mutect2, varscan2
- BACH2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 411/918 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1250663291, COSV100000868, COSV57586295; called by muse, mutect2, varscan2
- BAHCC1 | c.4564C>A p.L1522M | Missense Mutation (SNP) | VAF 300/696 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100311907; called by muse, mutect2
- BAHCC1 | c.5182C>T p.R1728W | Missense Mutation (SNP) | VAF 127/768 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782591995; called by muse, mutect2, varscan2
- BAHD1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 153/367 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs368071679; called by muse, mutect2, varscan2
- BAHD1 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 65/563 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768181332, COSV69083583; called by muse, mutect2, varscan2
- BAIAP3 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 204/523 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs371978318; called by muse, mutect2, varscan2
- BARHL2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 181/419 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs543375894; called by muse, mutect2, varscan2
- BASP1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 227/603 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758132970, COSV59469386; called by muse, mutect2, varscan2
- BAZ1A | c.3089C>A p.T1030N | Missense Mutation (SNP) | VAF 59/894 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100701165; called by muse, mutect2
- BAZ1A | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 172/786 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1416634265; called by muse, mutect2, varscan2
- BAZ2A | c.5366G>A p.R1789Q | Missense Mutation (SNP) | VAF 381/895 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200742397, COSV51639781; called by muse, mutect2, varscan2
- BAZ2B | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 450/1040 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs764609647, COSV58609868; called by muse, mutect2, varscan2
- BBS7 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 108/884 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); catalogued as rs764244818; called by muse, mutect2, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 262/637 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, varscan2
- BBX | c.1615T>C p.S539P | Missense Mutation (SNP) | VAF 195/1118 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV57895143; called by muse, mutect2, varscan2
- BCAS1 | c.725A>G p.D242G | Missense Mutation (SNP) | VAF 218/536 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781385361, COSV101006234; called by muse, mutect2, varscan2
- BCL11A | c.1549G>A p.V517M (on ENST00000335712 / NM_001365609.1; = p.V551M on NM_018014.4) | Missense Mutation (SNP) | VAF 206/472 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV59636716; called by muse, mutect2, varscan2
- BCL11B | c.2212G>A p.A738T (on ENST00000357195 / NM_001282237.2; = p.A667T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100595383; called by muse, mutect2
- BCL11B | c.1691G>A p.R564H (on ENST00000357195 / NM_001282237.2; = p.R493H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/624 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs1271709759, COSV100596027; called by muse, varscan2
- BCL2L12 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 74/532 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV99881019; called by muse, mutect2, varscan2
- BCL6B | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 267/683 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV53426433; called by muse, varscan2
- BCL9L | c.4153C>T p.R1385W | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs780991008; called by muse, mutect2, varscan2
- BCL9L | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 308/780 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1448489113, COSV52684109; called by muse, mutect2, varscan2
- BCOR | c.3240C>T p.C1080= | Splice Region (SNP) | VAF 267/568 reads (47%) | catalogued as rs768536546; called by muse, mutect2, varscan2
- BDH1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 201/588 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs115296714; called by muse, mutect2, varscan2
- BDNF | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 423/1063 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV59235596; called by muse, mutect2, varscan2
- BEND3 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 209/496 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1213131224; called by muse, mutect2, varscan2
- BICDL1 | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 112/929 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV104379929; called by muse, mutect2, varscan2
- BIRC2 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 382/989 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369921460, COSV57162110; called by muse, mutect2, varscan2
- BIRC6 | c.10997G>A p.R3666H | Missense Mutation (SNP) | VAF 366/937 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.921); catalogued as rs759663407, COSV101428247; called by muse, mutect2, varscan2
- BIRC6 | c.12103G>T p.D4035Y | Missense Mutation (SNP) | VAF 74/522 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV101134344; called by muse, mutect2, varscan2
- BLK | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 249/627 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52049879; called by muse, mutect2, varscan2
- BMERB1 | c.419+8C>T | Splice Region (SNP) | VAF 154/339 reads (45%) | catalogued as rs758521242; called by muse, mutect2, varscan2
- BMF | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs933674789, COSV99590468; called by muse, mutect2, varscan2
- BMP2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 281/710 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs377749107; called by muse, mutect2, varscan2
- BMP2K | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 409/976 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.299); catalogued as rs768868929, COSV99784892, COSV99785427; called by muse, varscan2
- BMP6 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 173/383 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as COSV51665301; called by muse, mutect2, varscan2
- BMPR1A | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 275/919 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs905457708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 382/894 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV65811613; called by muse, mutect2, varscan2
- BOC | c.2886+6G>A | Splice Region (SNP) | VAF 217/562 reads (39%) | catalogued as rs770186368; called by muse, mutect2, varscan2
- BOD1L1 | c.4223A>G p.D1408G | Missense Mutation (SNP) | VAF 42/1211 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99238154; called by muse, mutect2
- BOP1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 229/520 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs926150063; called by muse, mutect2, varscan2
- BPIFB2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 115/681 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs373260080; called by muse, mutect2, varscan2
- BPTF | c.5705C>T p.S1902F | Missense Mutation (SNP) | VAF 377/900 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58847998; called by muse, mutect2, varscan2
- BRAP | c.1685T>C p.I562T | Missense Mutation (SNP) | VAF 103/593 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1468723864; called by muse, mutect2, varscan2
- BRAP | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 154/726 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208386063, COSV100554015, COSV59538101; called by muse, mutect2, varscan2
- BRAT1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 203/452 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61394055, COSV61397335; called by muse, mutect2, varscan2
- BRCA2 | c.3422C>T p.T1141I | Missense Mutation (SNP) | VAF 358/978 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs397507308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.9931C>T p.P3311S | Missense Mutation (SNP) | VAF 411/974 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1275047772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10153C>T p.R3385C | Missense Mutation (SNP) | VAF 515/1180 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs397507261; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- BRD3 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV57704006; called by muse, mutect2
- BRD7 | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 447/1128 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as rs375265731, COSV54268645, COSV99576049; called by muse, mutect2, varscan2
- BRDT | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 399/1022 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV62868013; called by muse, mutect2, varscan2
- BRPF3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 214/484 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160592236, COSV60207201; called by muse, varscan2
- BRSK1 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 274/655 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58669228; called by muse, mutect2, varscan2
- BRWD1 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 534/1211 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58122763; called by muse, mutect2, varscan2
- BRWD3 | c.4336C>T p.P1446S | Missense Mutation (SNP) | VAF 135/950 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.107); catalogued as COSV64751661; called by muse, mutect2, varscan2
- BRWD3 | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 115/1042 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64746007; called by muse, mutect2, varscan2
- BSPRY | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 260/665 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs1016505275, COSV65243484; called by muse, mutect2, varscan2
- BTBD6 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 84/498 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs372576970; called by muse, mutect2, varscan2
- BTBD9 | c.1650C>A p.H550Q | Missense Mutation (SNP) | VAF 122/740 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58434844; called by muse, varscan2
- BTN2A1 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 218/487 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs748939213; called by muse, varscan2
- BUB1B | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 533/1191 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.936); catalogued as rs751509832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf105 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 99/710 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.074); catalogued as rs371701194, COSV56462245; called by muse, varscan2
- C10orf143 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 67/475 reads (14%) | catalogued as rs539297086; called by muse, mutect2, varscan2
- C10orf90 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 163/1031 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs1443728466, COSV52955357; called by muse, mutect2, varscan2
- C10orf90 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 198/467 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs369459666; called by muse, varscan2
- C10orf90 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 210/468 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs772583912, COSV52952791, COSV52965613; called by muse, varscan2
- C11orf21 | c.341G>A p.G114D (on ENST00000381153 / NM_001329958.2; = p.G160D on NM_001142946.3) | Missense Mutation (SNP) | VAF 323/770 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs995250840; called by muse, mutect2, varscan2
- C11orf94 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 252/675 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs1263077103; called by muse, mutect2, varscan2
- C12orf50 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 372/929 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1439582496, COSV100072214; called by muse, mutect2, varscan2
- C14orf39 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 251/623 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as rs768469771; called by muse, mutect2, varscan2
- C14orf93 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 266/603 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV52985592, COSV99400846; called by muse, mutect2, varscan2
- C15orf62 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1023401420; called by muse, mutect2, varscan2
- C17orf64 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 129/725 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs368635684, COSV52256363, COSV99293722; called by muse, mutect2, varscan2
- C17orf80 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 166/1180 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.673); catalogued as COSV52145221; called by muse, mutect2, varscan2
- C18orf63 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 358/828 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1186364385; called by muse, mutect2, varscan2
- C19orf18 | c.225G>A p.T75= | Splice Region (SNP) | VAF 100/565 reads (18%) | catalogued as rs771893067; called by muse, mutect2, varscan2
- C19orf44 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 237/534 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs751801097, COSV55609807; called by muse, mutect2, varscan2
- C1QB | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 228/544 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV59245744; called by muse, mutect2, varscan2
- C1R | c.1559C>A p.P520H (on ENST00000536053 / NM_001354346.2; = p.P506H on NM_001733.7) | Missense Mutation (SNP) | VAF 62/678 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV73382900; called by muse, mutect2
- C1R | c.485C>T p.S162F (on ENST00000536053 / NM_001354346.2; = p.S148F on NM_001733.7) | Missense Mutation (SNP) | VAF 455/1018 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56925339; called by muse, mutect2, varscan2
- C1S | c.870T>C p.D290= | Splice Region (SNP) | VAF 113/1142 reads (10%) | catalogued as rs782177634; called by muse, mutect2
- C1orf185 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 445/1045 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs754923183; called by muse, mutect2, varscan2
- C1orf198 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 361/807 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs753381372; called by muse, mutect2, varscan2
- C1orf43 | c.373C>T p.R125C (on ENST00000368521 / NM_001297718.2; = p.R91C on NM_015449.4) | Missense Mutation (SNP) | VAF 119/937 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs537167939, COSV62966002; called by muse, mutect2, varscan2
- C1orf87 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 459/1249 reads (37%) | catalogued as COSV64598396; called by muse, mutect2, varscan2
- C22orf23 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 387/909 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV50777986; called by muse, mutect2, varscan2
- C2CD2L | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 303/709 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs769498574, COSV100371450; called by mutect2, varscan2
- C2CD2L | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 71/1057 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776891538, COSV60884749; called by muse, mutect2
- C2CD4C | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 60/441 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs533023432; called by muse, varscan2
- C2CD4C | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 182/449 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV59966418; called by muse, varscan2
- C2CD4C | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 33/462 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as rs1568274242; called by muse, mutect2
- C2CD5 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 211/557 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1471759162, COSV61724558; called by muse, mutect2, varscan2
- C2CD6 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 415/988 reads (42%) | catalogued as COSV53792572; called by mutect2, varscan2
- C2orf49 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 416/1032 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs984823057, COSV51528527; called by muse, mutect2, varscan2
- C2orf80 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 516/1202 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.879); catalogued as rs750404525; called by muse, mutect2, varscan2
- C3 | c.4594C>T p.R1532W | Missense Mutation (SNP) | VAF 437/1127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199911426; called by muse, mutect2, varscan2
- C3 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 38/802 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1199323072, COSV55579919; called by muse, mutect2
- C3AR1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 100/688 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs371493019; called by muse, mutect2, varscan2
- C4orf54 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 103/696 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.224); catalogued as rs866337486; called by muse, varscan2
- C5orf47 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 90/452 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1389485413; called by muse, mutect2, varscan2
- C6orf118 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 332/760 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.492); catalogued as rs776425936; called by muse, mutect2, varscan2
- C7orf65 | n.105G>A | Splice Region (SNP) | VAF 279/727 reads (38%) | catalogued as rs1348685127; called by muse, mutect2, varscan2
- C8A | c.1632C>A p.C544* | Nonsense Mutation (SNP) | VAF 353/895 reads (39%) | catalogued as rs751928361; called by muse, mutect2, varscan2
- C8G | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 266/614 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs751173089; called by muse, varscan2
- CA14 | c.975T>G p.S325R | Missense Mutation (SNP) | VAF 300/821 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.112); catalogued as rs149477256; called by muse, mutect2, varscan2
- CA4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 350/823 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs777463944, COSV56281014; called by muse, mutect2, varscan2
- CABIN1 | c.3587G>A p.R1196H | Missense Mutation (SNP) | VAF 341/834 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs752877361, COSV54081371; called by muse, mutect2, varscan2
- CABLES2 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 58/1093 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV54157403, COSV54158698; called by muse, mutect2
- CACHD1 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 381/937 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as rs140399585; called by muse, mutect2, varscan2
- CACNA1A | c.5785C>T p.R1929W | Missense Mutation (SNP) | VAF 90/884 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100803349; called by muse, mutect2, varscan2
- CACNA1A | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 43/1340 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.154); catalogued as rs1335209785, COSV100801586; called by muse, mutect2
- CACNA1B | c.3892G>A p.V1298I | Missense Mutation (SNP) | VAF 484/1178 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as rs778050908, COSV53144208; called by muse, mutect2, varscan2
- CACNA1C | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 42/921 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100222230; called by muse, mutect2
- CACNA1D | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 215/518 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99858209; called by muse, mutect2, varscan2
- CACNA1D | c.1750G>A p.V584I (on ENST00000350061 / NM_001128840.3; = p.V604I on NM_000720.4) | Missense Mutation (SNP) | VAF 459/1047 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs773365038, COSV55436324, COSV55437532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1F | c.5618G>A p.R1873H | Missense Mutation (SNP) | VAF 93/532 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs782778888, COSV59907169; called by muse, mutect2, varscan2
- CACNA1H | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 46/729 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867971335; called by muse, mutect2
- CACNA1H | c.4165G>A p.A1389T | Missense Mutation (SNP) | VAF 244/621 reads (39%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.988); catalogued as rs758458100; called by muse, mutect2, varscan2
- CACNA1H | c.4759+8G>A | Splice Region (SNP) | VAF 180/476 reads (38%) | catalogued as rs199997129; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D3 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 213/1175 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.29); catalogued as rs755514944; called by muse, mutect2, varscan2
- CACNB1 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 295/702 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as rs1400061874; called by muse, mutect2, varscan2
- CACNB2 | c.1625G>A p.R542H (on ENST00000324631 / NM_201596.3; = p.R487H on NM_000724.4) | Missense Mutation (SNP) | VAF 406/924 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs571637787, COSV56647937; called by muse, mutect2, varscan2
- CACNB2 | c.1976G>A p.R659H (on ENST00000324631 / NM_201596.3; = p.R604H on NM_000724.4) | Missense Mutation (SNP) | VAF 208/620 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs780134367, COSV99993498; called by muse, mutect2, varscan2
- CACTIN | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 338/766 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1459093992, COSV50270872; called by muse, varscan2
- CAD | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 532/1167 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs770968496; called by muse, mutect2, varscan2
- CAD | c.4471G>A p.A1491T | Missense Mutation (SNP) | VAF 263/642 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs138928198; called by muse, mutect2, varscan2
- CADPS | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 263/705 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375576173; called by muse, mutect2, varscan2
- CALCA | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 374/870 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1020077076; called by muse, mutect2, varscan2
- CALHM6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 335/923 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs199779640, COSV100889473; called by muse, mutect2, varscan2
- CAMK1D | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 64/1224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257797457, COSV66610289; called by muse, mutect2
- CAMK1G | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 352/878 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV50523432; called by muse, mutect2, varscan2
- CAMK2G | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 228/599 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as CM1211472; called by muse, mutect2, varscan2
- CAMK2G | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 379/894 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs775452990; called by muse, mutect2, varscan2
- CAMSAP3 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 93/660 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1009943636; called by muse, mutect2, varscan2
- CAMTA1 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 441/1024 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs759300229; called by muse, varscan2
- CAMTA1 | c.4301G>A p.S1434N | Missense Mutation (SNP) | VAF 372/866 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs202096889; called by muse, mutect2, varscan2
- CAND1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 161/438 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV101598297; called by muse, mutect2, varscan2
- CAND2 | c.493C>T p.L165= (on ENST00000456430 / NM_001162499.2; = p.L72= on NM_012298.3) | Splice Region (SNP) | VAF 157/289 reads (54%) | catalogued as rs575105008; called by muse, mutect2, varscan2
- CAND2 | c.1621G>T p.A541S (on ENST00000456430 / NM_001162499.2; = p.A448S on NM_012298.3) | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs1044429842; called by muse, mutect2, varscan2
- CAND2 | c.2456C>T p.A819V (on ENST00000456430 / NM_001162499.2; = p.A726V on NM_012298.3) | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs779288491, COSV55994885; called by muse, mutect2, varscan2
- CAND2 | c.3266C>T p.A1089V (on ENST00000456430 / NM_001162499.2; = p.A972V on NM_012298.3) | Missense Mutation (SNP) | VAF 338/817 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200074296; called by muse, mutect2, varscan2
- CANT1 | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 40/713 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV56605518; called by muse, mutect2
- CAPN1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 274/619 reads (44%) | catalogued as rs751243573, COSV54201789; called by muse, mutect2, varscan2
- CAPN10 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 52/551 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs368540986; called by muse, mutect2
- CAPN13 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 252/693 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.537); catalogued as rs369616026; called by muse, mutect2, varscan2
- CAPN14 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 276/709 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs369874328; called by muse, mutect2, varscan2
- CAPN5 | c.770G>A p.R257H (on ENST00000456580; = p.R217H on NM_004055.5) | Missense Mutation (SNP) | VAF 276/699 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs202032027; called by muse, mutect2, varscan2
- CARD11 | c.2186A>G p.D729G | Missense Mutation (SNP) | VAF 78/982 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV62756683; called by muse, mutect2
- CARD19 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 240/585 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs752738422, COSV100968717; called by muse, varscan2
- CARMIL1 | c.2457A>C p.K819N | Missense Mutation (SNP) | VAF 411/1038 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as COSV61520584; called by muse, mutect2, varscan2
- CARMIL2 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 276/670 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1306909529, COSV54665567; called by muse, mutect2, varscan2
- CARS1 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 72/1343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1438541322, COSV99542665; called by muse, mutect2
- CASKIN1 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 240/596 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100623808; called by muse, mutect2, varscan2
- CASKIN1 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 191/491 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764510057; called by muse, mutect2, varscan2
- CASP4 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 469/1098 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs905135501, COSV67744839; called by muse, mutect2, varscan2
- CASP8AP2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 135/1024 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.784); catalogued as rs377049861; called by muse, mutect2, varscan2
- CASZ1 | c.3421G>A p.A1141T | Missense Mutation (SNP) | VAF 320/779 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs370619445; called by muse, mutect2, varscan2
- CAT | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 411/992 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768085681; called by muse, mutect2, varscan2
- CATSPER1 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 173/951 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs772852592, COSV56413366; called by muse, mutect2, varscan2
- CATSPER1 | c.685T>G p.S229A | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.121); catalogued as rs748003564; called by muse, mutect2
- CATSPERB | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 109/656 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.431); catalogued as rs150597625, COSV56430492; called by muse, mutect2, varscan2
- CATSPERB | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 373/980 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs139686935; called by muse, mutect2, varscan2
- CATSPERD | c.1185A>C p.E395D | Missense Mutation (SNP) | VAF 73/695 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1042518586; called by mutect2, varscan2
- CBLL1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 78/774 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV56028609; called by muse, mutect2, varscan2
- CBLL2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 78/665 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs371087148, COSV60369056; called by muse, varscan2
- CBWD6 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 512/978 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs1419512400; called by muse, mutect2, varscan2
- CBY2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 192/502 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV100137916, COSV60119956; called by muse, varscan2
- CC2D1A | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 258/644 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs370497699; called by muse, mutect2, varscan2
- CCDC114 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 299/690 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs376555574; called by muse, mutect2, varscan2
- CCDC120 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 285/639 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782426708; called by muse, mutect2, varscan2
- CCDC130 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 149/354 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs990411946, COSV50004845; called by muse, mutect2, varscan2
- CCDC138 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 517/1343 reads (38%) | catalogued as rs768858881; called by muse, mutect2, varscan2
- CCDC149 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 499/1188 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs755220017; called by muse, varscan2
- CCDC150 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 552/1479 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs781642729, COSV55871577; called by muse, mutect2, varscan2
- CCDC157 | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 164/523 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs139750381, COSV53176883; called by muse, mutect2, varscan2
- CCDC169 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 343/822 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs1037697107, COSV53484088; called by muse, mutect2, varscan2
- CCDC174 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 514/1131 reads (45%) | catalogued as rs752013404; called by muse, mutect2, varscan2
- CCDC177 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 180/488 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196866664; called by muse, varscan2
- CCDC180 | c.4333C>T p.R1445W | Missense Mutation (SNP) | VAF 362/825 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs141047389; called by muse, mutect2, varscan2
- CCDC185 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 248/610 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.33); catalogued as rs1261394700; called by muse, mutect2
- CCDC190 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 59/566 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100905834; called by muse, mutect2, varscan2
- CCDC27 | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 46/904 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as rs868489245; called by muse, mutect2
- CCDC60 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 307/742 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs200062829, COSV59546033; called by muse, mutect2, varscan2
- CCDC63 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 336/769 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100370666; called by muse, mutect2, varscan2
- CCDC68 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 240/656 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs771391383, COSV61604209; called by muse, mutect2
- CCDC70 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 137/998 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs61730661; called by muse, mutect2, varscan2
- CCDC71 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 302/727 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.602); catalogued as rs1014856859, COSV58910657; called by muse, mutect2, varscan2
- CCDC71 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 119/554 reads (21%) | catalogued as rs777888455, COSV58910694; called by muse, mutect2, varscan2
- CCDC77 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 265/624 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189099875; called by muse, mutect2, varscan2
- CCDC8 | c.1160C>A p.A387D | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100281943; called by mutect2, varscan2
- CCDC80 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 92/516 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs767753684; called by muse, varscan2
- CCDC83 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 175/1404 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV54699913; called by muse, mutect2, varscan2
- CCDC88A | c.3110C>T p.T1037M | Missense Mutation (SNP) | VAF 441/1078 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs376732011; called by muse, mutect2, varscan2
- CCDC88C | c.5940G>T p.K1980N | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV57796721; called by muse, mutect2, varscan2
- CCDC88C | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 157/393 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs745564345, COSV66239514; called by muse, varscan2
- CCDC88C | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 166/399 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs751298743; called by muse, varscan2
- CCDC88C | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 190/577 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs770066487, COSV66233787; called by muse, mutect2, varscan2
- CCDC9 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 262/550 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs202227718, COSV55722903; called by muse, mutect2
- CCDC9 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 375/827 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs756329425; called by muse, mutect2, varscan2
- CCER1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 219/577 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1242580134, COSV62647948; called by muse, mutect2, varscan2
- CCIN | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 280/676 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs761530671; called by muse, varscan2
- CCIN | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 319/764 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.372); catalogued as rs774663624; called by muse, mutect2, varscan2
- CCN3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 205/517 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52385658; called by muse, mutect2, varscan2
- CCNA1 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 353/929 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55222163; called by muse, mutect2, varscan2
- CCNB3 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 370/985 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99328362, COSV99328995; called by muse, mutect2, varscan2
- CCNF | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 156/1092 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99564149; called by mutect2, varscan2
- CCNG2 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 169/1068 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs761779386; called by muse, varscan2
- CCNQ | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 96/648 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs781948889, COSV52344096; called by muse, varscan2
- CCNT2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 363/715 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs769555288, COSV99751031; called by muse, mutect2, varscan2
- CCR5 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 237/570 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52752727; called by muse, mutect2, varscan2
- CCSER1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 492/1164 reads (42%) | catalogued as rs775072687; called by muse, varscan2
- CCT5 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 58/1184 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV54725515; called by muse, mutect2
- CD101 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 32/740 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1162423411; called by muse, mutect2
- CD109 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 418/1081 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747748880; called by muse, mutect2, varscan2
- CD1A | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 91/672 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779636773, COSV56864039; called by muse, mutect2, varscan2
- CD247 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 270/663 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as rs1162990874, COSV62980249; called by muse, varscan2
- CD300A | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 450/1060 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV60410120; called by muse, mutect2, varscan2
- CD33 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 254/610 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs1395035314, COSV51803178; called by muse, mutect2, varscan2
- CD33 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 429/936 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV51801343; called by muse, mutect2, varscan2
- CD3D | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 262/750 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs375444192; called by muse, mutect2, varscan2
- CD6 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 475/1136 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV57839278; called by muse, mutect2, varscan2
- CD72 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 437/998 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs756816514; called by muse, mutect2, varscan2
- CD81 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 240/593 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs760727392; called by muse, mutect2, varscan2
- CD82 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 67/658 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs143845294; called by muse, varscan2
- CDAN1 | c.2185T>G p.L729V | Missense Mutation (SNP) | VAF 103/663 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748032155; called by muse, mutect2, varscan2
- CDC14B | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 336/1064 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1441359507; called by muse, varscan2
- CDC20 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 125/732 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs867593106; called by muse, mutect2, varscan2
- CDC20B | c.698A>C p.Y233S | Missense Mutation (SNP) | VAF 293/694 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99696667; called by muse, mutect2, varscan2
- CDC42BPA | c.4558G>A p.E1520K (on ENST00000334218 / NM_001366019.2; = p.E1507K on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 355/915 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs755208656; called by muse, mutect2, varscan2
- CDC42BPB | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 90/662 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775258; called by muse, varscan2
- CDC42BPG | c.3422G>A p.S1141N | Missense Mutation (SNP) | VAF 224/518 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as rs778495549; called by muse, mutect2, varscan2
- CDC42BPG | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 281/667 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs776140099; called by muse, mutect2, varscan2
- CDC42BPG | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1282787299; called by muse, mutect2, varscan2
- CDC6 | c.180C>T p.G60= | Splice Region (SNP) | VAF 308/616 reads (50%) | catalogued as rs187582006; called by muse, mutect2, varscan2
- CDCA2 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 513/1073 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100399211; called by muse, mutect2, varscan2
- CDCA2 | c.1486T>C p.S496P | Missense Mutation (SNP) | VAF 418/1058 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs777369910; called by muse, mutect2, varscan2
- CDCA7 | c.683G>A p.R228H (on ENST00000347703 / NM_145810.3; = p.R307H on NM_031942.5) | Missense Mutation (SNP) | VAF 90/1102 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs749651449, COSV100143728; called by muse, mutect2
- CDCA7L | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 364/905 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138465359; called by muse, mutect2, varscan2
- CDH11 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 227/516 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763336652, COSV51763225, COSV99217174; called by muse, mutect2, varscan2
- CDH12 | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 385/887 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1221586757, COSV101200819; called by muse, mutect2, varscan2
- CDH12 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 101/654 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1465712081, COSV66392941, COSV66421592; called by muse, mutect2, varscan2
- CDH16 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 210/479 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55338241; called by muse, mutect2, varscan2
- CDH17 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 512/1159 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs765167154; called by muse, mutect2, varscan2
- CDH22 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 397/927 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV100952811; called by muse, mutect2, varscan2
- CDH26 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 424/1083 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs770853281, COSV54844816; called by muse, mutect2, varscan2
- CDH5 | c.1421A>G p.D474G | Missense Mutation (SNP) | VAF 48/1140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58517769; called by muse, mutect2
- CDH6 | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 110/555 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs185351199; called by muse, mutect2, varscan2
- CDH7 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 110/938 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV59889568; called by muse, mutect2, varscan2
- CDHR2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs762011542, COSV56140280, COSV99991810; called by muse, mutect2, varscan2
- CDHR3 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 478/1141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754877338; called by muse, mutect2, varscan2
- CDK5RAP2 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 500/1178 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs764423192; called by muse, mutect2, varscan2
- CDK9 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 289/777 reads (37%) | catalogued as rs754446615; called by muse, mutect2, varscan2
- CDKAL1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 102/1130 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs1306798050, COSV99215877; called by muse, mutect2
- CDKL2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 64/996 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1553931750; called by muse, mutect2
- CDON | c.1852-4G>A | Splice Region (SNP) | VAF 336/861 reads (39%) | catalogued as rs528444588; called by muse, mutect2, varscan2
- CEACAM4 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 170/451 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV55731832; called by muse, mutect2, varscan2
- CEBPZ | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 58/1198 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs992432583; called by muse, mutect2
- CELA2B | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 104/687 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV101025860; called by muse, varscan2
- CELF5 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as rs761185897; called by muse, mutect2, varscan2
- CELSR1 | c.8000C>T p.T2667I | Missense Mutation (SNP) | VAF 138/563 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781221913; called by muse, varscan2
- CELSR2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 283/663 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54771582; called by muse, mutect2, varscan2
- CELSR2 | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 270/658 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs987828949; called by muse, mutect2, varscan2
- CELSR2 | c.6803G>A p.R2268H | Missense Mutation (SNP) | VAF 65/913 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs999842399; called by muse, mutect2
- CENPF | c.4417G>A p.V1473I | Missense Mutation (SNP) | VAF 335/805 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs754206129, COSV65274951; called by muse, mutect2, varscan2
- CENPF | c.9022G>A p.A3008T | Missense Mutation (SNP) | VAF 158/983 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs760831724; called by muse, mutect2, varscan2
- CENPI | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 399/894 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs1007223558; called by muse, mutect2, varscan2
- CENPM | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 321/707 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs374540211; called by muse, mutect2, varscan2
- CENPT | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 357/853 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs779684299, COSV54650304, COSV54650752, COSV99535160; called by muse, mutect2, varscan2
- CEP112 | c.2542G>A p.D848N (on ENST00000392769 / NM_001353127.1; = p.D104N on NM_001037325.3) | Missense Mutation (SNP) | VAF 590/1367 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1295466476; called by muse, mutect2, varscan2
- CEP135 | c.3086C>T p.T1029I | Missense Mutation (SNP) | VAF 120/989 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1239232514; called by muse, varscan2
- CEP162 | c.286T>C p.S96P | Missense Mutation (SNP) | VAF 375/862 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1276115719; called by muse, mutect2, varscan2
- CEP164 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 112/827 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1369743665; called by muse, mutect2, varscan2
- CEP170B | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 42/752 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985734954; called by muse, mutect2
- CEP170B | c.215G>A p.R72H (on ENST00000453495; = p.R2H on NM_015005.3) | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759694034, COSV69023801; called by muse, mutect2, varscan2
- CEP170B | c.2692G>A p.A898T (on ENST00000453495; = p.A827T on NM_015005.3) | Missense Mutation (SNP) | VAF 174/417 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs758620472; called by muse, mutect2, varscan2
- CEP170B | c.3811G>A p.G1271S (on ENST00000453495; = p.G1200S on NM_015005.3) | Missense Mutation (SNP) | VAF 180/479 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs751121573; called by muse, mutect2, varscan2
- CEP290 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 377/956 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99898043; called by muse, mutect2, varscan2
- CEP295 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 562/1318 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs1485508205; called by muse, mutect2, varscan2
- CEP350 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 368/954 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV62485972; called by muse, mutect2, varscan2
- CEP350 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 106/820 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149644649; called by muse, mutect2, varscan2
- CEP57 | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 285/706 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV57687556; called by muse, mutect2, varscan2
- CEP68 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 340/848 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1477029762; called by muse, mutect2, varscan2
- CERS2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 392/1018 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1234682447; called by muse, mutect2, varscan2
- CERS4 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 32/758 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as rs1027006474; called by muse, mutect2
- CFAP251 | c.1194C>T p.N398= | Splice Region (SNP) | VAF 36/348 reads (10%) | catalogued as rs1391154742; called by muse, varscan2
- CFAP251 | c.3280C>A p.L1094M | Missense Mutation (SNP) | VAF 76/1010 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99995561; called by muse, mutect2
- CFAP46 | c.6583G>T p.A2195S | Missense Mutation (SNP) | VAF 106/995 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV99583858; called by muse, mutect2, varscan2
- CFAP46 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 426/1079 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183052837; called by muse, mutect2, varscan2
- CFAP47 | c.6958G>A p.A2320T | Missense Mutation (SNP) | VAF 382/896 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs868978425; called by muse, mutect2, varscan2
- CFAP47 | c.8026C>T p.Q2676* | Nonsense Mutation (SNP) | VAF 44/1306 reads (3%) | catalogued as COSV101073551; called by muse, mutect2
- CFAP52 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 114/982 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs747187180; called by muse, mutect2, varscan2
- CFAP57 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 508/1219 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs537699818, COSV63016762; called by muse, mutect2, varscan2
- CFAP65 | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs766294264; called by muse, mutect2, varscan2
- CFB | c.1408+1G>A p.X470_splice | Splice Site (SNP) | VAF 58/625 reads (9%) | catalogued as rs111740650; called by muse, mutect2
- CFHR4 | c.1307C>A p.S436Y (on ENST00000367416 / NM_001201551.2; = p.S190Y on NM_006684.5) | Missense Mutation (SNP) | VAF 356/851 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52235177, COSV99260064; called by muse, mutect2, varscan2
- CFTR | c.3011C>A p.A1004D | Missense Mutation (SNP) | VAF 202/581 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CD057608; called by muse, mutect2, varscan2
- CGB1 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.979); catalogued as rs1311038616; called by muse, mutect2, varscan2
- CGB5 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs201373221; called by muse, varscan2
- CGNL1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 356/846 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs772369065; called by muse, mutect2, varscan2
- CHADL | c.2222G>A p.R741K | Missense Mutation (SNP) | VAF 121/902 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV53431790, COSV53432443; called by muse, mutect2, varscan2
- CHAF1A | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 446/1107 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1251104917, COSV56672232; called by muse, mutect2, varscan2
- CHAF1B | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 430/940 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1447517597, COSV58439508; called by muse, varscan2
- CHD2 | c.3370C>T p.R1124W | Missense Mutation (SNP) | VAF 70/1221 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1454060267; called by muse, mutect2
- CHD6 | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 402/950 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781626853; called by mutect2, varscan2
- CHD7 | c.4446C>A p.F1482L | Missense Mutation (SNP) | VAF 323/790 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV71112810; called by mutect2, varscan2
- CHD8 | c.5975G>A p.R1992H (on ENST00000646647 / NM_001170629.2; = p.R1713H on NM_020920.4) | Missense Mutation (SNP) | VAF 133/762 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs372488156, COSV63036670; called by muse, mutect2, varscan2
- CHD8 | c.1861C>T p.P621S (on ENST00000646647 / NM_001170629.2; = p.P342S on NM_020920.4) | Missense Mutation (SNP) | VAF 324/845 reads (38%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.447); catalogued as rs746637522; called by muse, varscan2
- CHD9 | c.2717G>A p.G906D | Missense Mutation (SNP) | VAF 419/954 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1213461387, COSV54613251; called by muse, mutect2, varscan2
- CHERP | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 80/483 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52222811; called by muse, mutect2, varscan2
- CHFR | c.1316C>T p.A439V (on ENST00000432561 / NM_001161345.1; = p.A398V on NM_018223.2) | Missense Mutation (SNP) | VAF 293/647 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs371541325; called by muse, mutect2, varscan2
- CHFR | c.1111C>T p.R371C (on ENST00000432561 / NM_001161345.1; = p.R330C on NM_018223.2) | Missense Mutation (SNP) | VAF 323/776 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1210874026, COSV57177443; called by muse, mutect2
- CHIA | c.1271C>T p.S424L (on ENST00000343320; = p.S316L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 275/689 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs754393219, COSV58475780; called by muse, mutect2, varscan2
- CHIC1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 362/899 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as rs373733681, COSV65157737; called by muse, mutect2, varscan2
- CHMP1A | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 429/1005 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs767659184, COSV99498312; called by muse, mutect2, varscan2
- CHMP2A | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 69/845 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.652); catalogued as rs763733145, COSV53396468; called by muse, mutect2
- CHPF | c.1508C>T p.T503I | Missense Mutation (SNP) | VAF 77/496 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1227024844; called by muse, mutect2, varscan2
- CHPT1 | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 158/418 reads (38%) | catalogued as COSV57533519; called by muse, mutect2, varscan2
- CHRAC1 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754092232; called by mutect2, varscan2
- CHRM4 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63126496; called by muse, mutect2, varscan2
- CHRNA5 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 298/716 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs141180754; called by muse, mutect2, varscan2
- CHRNA9 | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 125/874 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); catalogued as rs181978594; called by muse, mutect2, varscan2
- CHRNB2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 50/836 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as rs1421654764, COSV63807815; called by muse, mutect2
- CHRNE | c.1197G>T p.R399S | Missense Mutation (SNP) | VAF 48/726 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); catalogued as rs867064180; called by muse, mutect2
- CHST10 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 331/802 reads (41%) | catalogued as rs370119165; called by muse, mutect2, varscan2
- CHST12 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 210/551 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as rs1430278569, COSV99324329; called by muse, mutect2, varscan2
- CHST12 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1362474794; called by muse, mutect2, varscan2
- CHST15 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 350/864 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs375999783; called by muse, mutect2, varscan2
- CHST5 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 143/560 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as rs774087462, COSV100291794; called by muse, mutect2, varscan2
- CHST7 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 167/328 reads (51%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as rs762875012, COSV104370233; called by muse, mutect2, varscan2
- CHST8 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 216/502 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs759269411, COSV52858505, COSV52863873; called by muse, mutect2, varscan2
- CIAO2B | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 209/550 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV57698186; called by muse, mutect2, varscan2
- CIAO3 | c.693+8C>T | Splice Region (SNP) | VAF 197/470 reads (42%) | catalogued as rs1324974281; called by muse, mutect2, varscan2
- CIBAR2 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 156/947 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs563398420; called by muse, varscan2
- CIBAR2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 39/809 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101608291; called by muse, mutect2
- CIDEA | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 235/577 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs1487889120; called by muse, mutect2, varscan2
- CIDEB | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 204/475 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs146066890; called by muse, mutect2, varscan2
- CILK1 | c.1804C>T p.R602* (on ENST00000350082 / NM_001375397.1; = p.R595* on NM_014920.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 383/921 reads (42%) | catalogued as rs771374942, COSV63155750; called by muse, mutect2, varscan2
- CLBA1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 199/531 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101120942; called by muse, mutect2, varscan2
- CLCA2 | c.1988C>A p.A663D | Missense Mutation (SNP) | VAF 132/334 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755836978; called by muse, mutect2, varscan2
- CLCN1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 297/671 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546411827, CM110920, COSV58368188; ClinVar: uncertain significance; called by muse, varscan2
- CLCN7 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 332/748 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766116666, COSV99247269; called by muse, mutect2, varscan2
- CLCN7 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 292/788 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM013520, CM034392; called by muse, varscan2
- CLDN9 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867461598; called by muse, mutect2
- CLEC12A | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 277/781 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs746425631, COSV58561801; called by muse, mutect2, varscan2
- CLEC2B | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 98/652 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs779592063; called by muse, mutect2, varscan2
- CLEC3A | c.532C>A p.L178M (on ENST00000651443; = p.L169M on NM_005752.6) | Missense Mutation (SNP) | VAF 407/911 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV55222222; called by muse, mutect2, varscan2
- CLEC3B | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 285/700 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1348676016; called by muse, mutect2, varscan2
- CLEC4A | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 531/1211 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs373496736, COSV99983588; called by muse, mutect2, varscan2
- CLECL1 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 373/1011 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100590136; called by muse, mutect2, varscan2
- CLIC4 | c.416-1G>A p.X139_splice | Splice Site (SNP) | VAF 449/1098 reads (41%) | catalogued as COSV65525963; called by muse, mutect2, varscan2
- CLIC6 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs780870930; called by muse, varscan2
- CLIP1 | c.3719C>T p.A1240V (on ENST00000620786 / NM_001247997.1; = p.A1229V on NM_002956.2) | Missense Mutation (SNP) | VAF 428/1062 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751898190; called by muse, mutect2, varscan2
- CLIP1 | c.1894G>A p.A632T (on ENST00000620786 / NM_001247997.1; = p.A621T on NM_002956.2) | Missense Mutation (SNP) | VAF 424/967 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs151267608; called by muse, mutect2, varscan2
- CLIP3 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 191/362 reads (53%) | catalogued as COSV62112172; called by muse, mutect2, varscan2
- CLN3 | c.1087G>A p.A363T (on ENST00000360019 / NM_001286104.2; = p.A387T on NM_000086.2) | Missense Mutation (SNP) | VAF 317/866 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768614719, COSV61105524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLN6 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 84/675 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as CM152578; called by muse, mutect2, varscan2
- CLPB | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 222/621 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs778955282, COSV53633330; called by muse, mutect2, varscan2
- CLSTN1 | c.1136C>T p.S379L (on ENST00000377298 / NM_001009566.3; = p.S369L on NM_014944.4) | Missense Mutation (SNP) | VAF 324/767 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs267598783; called by muse, varscan2
- CLSTN1 | c.434C>A p.S145Y (on ENST00000377298 / NM_001009566.3; = p.S135Y on NM_014944.4) | Missense Mutation (SNP) | VAF 86/612 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63648085; called by muse, varscan2
- CLSTN2 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 394/952 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV71723732; called by muse, mutect2, varscan2
- CLUAP1 | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 46/922 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as COSV57089890; called by muse, mutect2
- CLUH | c.44C>T p.A15V (on ENST00000435359; = p.A53V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 340/873 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs761532142, COSV101425908; called by muse, mutect2, varscan2
- CMIP | c.757C>T p.R253W (on ENST00000537098 / NM_198390.2; = p.R159W on NM_030629.3) | Missense Mutation (SNP) | VAF 215/577 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs750221720, COSV101220950; called by muse, mutect2, varscan2
- CMIP | c.1085C>T p.P362L (on ENST00000537098 / NM_198390.2; = p.P268L on NM_030629.3) | Missense Mutation (SNP) | VAF 392/878 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs760254009, COSV67699162; called by muse, mutect2, varscan2
- CMKLR1 | c.1069T>C p.S357P (on ENST00000312143 / NM_001142344.2; = p.S355P on NM_004072.3) | Missense Mutation (SNP) | VAF 43/1127 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV56438645; called by muse, mutect2
- CNMD | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 372/908 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1201015797, COSV65033616; called by muse, mutect2, varscan2
- CNOT1 | c.2714A>G p.Y905C | Missense Mutation (SNP) | VAF 399/1000 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55314469; called by muse, mutect2, varscan2
13,584 further variants in this file (8,262 protein-altering or splice-affecting, 2,846 silent, 2,476 other) are not listed here.
